Somatic mutation profile of tumor specimen 0DN3SQ from CCDI case PBCBDL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.0 years (4,391 days).
Specimen 0DN3SQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 363d5f9b-62fb-4f61-8602-6849e37863df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN3R5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4368488-9c23-41db-b27c-812080594197

The open-access MAF lists 66 somatic variants for this specimen: 36 protein-altering or splice-affecting, 22 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 22, Intron 5, 3'UTR 2, Nonsense Mutation 1, Splice Region 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCORL1 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 182/338 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as rs375680936, COSV54399678; called by muse, varscan2
- BTBD8 | c.4922A>G p.D1641G (on ENST00000636805 / NM_001376131.1; = p.D1128G on NM_015237.4) | Missense Mutation (SNP) | VAF 291/584 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as rs1314508391; called by muse, varscan2
- CACNA1C | c.5896C>T p.R1966* (on ENST00000399634 / NM_001167625.1; = p.R1895* on NM_000719.7) | Nonsense Mutation (SNP) | VAF 353/827 reads (43%) | catalogued as rs1556290584, COSV59716172; called by muse, varscan2
- CCDC120 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 272/678 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782816201, COSV64515054; called by muse, varscan2
- COL1A2 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 216/506 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs773392397; called by muse, varscan2
- FAM155B | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 144/414 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.082); catalogued as COSV52935668; called by muse, varscan2
- FAM236C | c.212+2C>T p.X71_splice | Splice Site (SNP) | VAF 194/852 reads (23%) | catalogued as rs1445719489; called by muse, varscan2
- GPR37 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 166/1080 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs200937236, COSV58258381; called by muse, varscan2
- HNRNPM | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 56/390 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.538); catalogued as COSV55313535; called by muse, varscan2
- HUNK | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 208/1114 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs780565997, COSV54235641; called by muse, varscan2
- JAK3 | c.2070G>T p.W690C | Missense Mutation (SNP) | VAF 303/772 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71687047; called by muse, varscan2
- MTUS2 | c.711G>T p.E237D | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV101462094, COSV101462169; called by muse, varscan2
- OR2AP1 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 138/749 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.904); catalogued as rs761550919; called by muse, varscan2
- OR5M11 | c.857C>A p.P286Q | Missense Mutation (SNP) | VAF 281/955 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101602036; called by muse, varscan2
- PLXNA2 | c.4287G>T p.R1429S | Missense Mutation (SNP) | VAF 474/2408 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100885690; called by muse, varscan2
- PPP1R16B | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 187/475 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as rs776263972; called by muse, varscan2
- TSEN54 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 457/1084 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1339810525; called by muse, varscan2
- A2M | c.3946G>A p.V1316M | Missense Mutation (SNP) | VAF 120/825 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); called by muse, varscan2
- AGPS | c.16G>C p.A6P | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, varscan2
- ALDOB | c.184A>T p.I62F | Missense Mutation (SNP) | VAF 160/702 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, varscan2
- ATF7IP | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 568/1226 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); called by muse, varscan2
- CSTF2 | c.1365G>C p.M455I | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); called by muse, varscan2
- D2HGDH | c.646T>C p.Y216H | Missense Mutation (SNP) | VAF 349/674 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, varscan2
- FGF16 | c.555C>A p.H185Q | Missense Mutation (SNP) | VAF 128/886 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.613); called by muse, varscan2
- GATA2 | c.974T>A p.M325K | Missense Mutation (SNP) | VAF 348/692 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- IQGAP3 | c.3808G>A p.D1270N | Missense Mutation (SNP) | VAF 902/1394 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, varscan2
- MCMDC2 | c.1095C>A p.N365K | Missense Mutation (SNP) | VAF 66/515 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, varscan2
- NHSL1 | c.899G>A p.G300D | Missense Mutation (SNP) | VAF 78/658 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, varscan2
- NUP133 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 78/627 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.598); called by muse, varscan2
- OR4K15 | c.952G>A p.V318M (on ENST00000305051; = p.V294M on NM_001005486.1) | Missense Mutation (SNP) | VAF 186/756 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.042); called by muse, varscan2
- PALB2 | c.2834+8A>T | Splice Region (SNP) | VAF 104/616 reads (17%) | called by muse, varscan2
- SAMD7 | c.818A>G p.K273R | Missense Mutation (SNP) | VAF 408/920 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, varscan2
- STAB2 | c.3261G>T p.L1087F | Missense Mutation (SNP) | VAF 353/828 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, varscan2
- THOC5 | c.196A>G p.M66V | Missense Mutation (SNP) | VAF 104/833 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.341); called by muse, varscan2
- USP51 | c.1801C>A p.H601N | Missense Mutation (SNP) | VAF 506/1168 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, varscan2
- ZNF324B | c.813C>A p.D271E | Missense Mutation (SNP) | VAF 128/318 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.39); called by muse, varscan2
- AC231657.3 | c.525C>T p.Y175= | Silent (SNP) | VAF 138/302 reads (46%) | catalogued as COSV59875626; called by muse, varscan2
- ALMS1 | c.7977T>C p.P2659= | Silent (SNP) | VAF 166/740 reads (22%) | called by muse, varscan2
- BMP5 | c.1311T>C p.N437= | Silent (SNP) | VAF 400/910 reads (44%) | catalogued as COSV63707361; called by muse, varscan2
- CCNB3 | c.1975T>C p.L659= | Silent (SNP) | VAF 311/744 reads (42%) | called by muse, varscan2
- CFAP54 | c.3549A>G p.G1183= | Silent (SNP) | VAF 246/583 reads (42%) | called by muse, varscan2
- CYSLTR1 | c.735T>C p.S245= | Silent (SNP) | VAF 168/1118 reads (15%) | called by muse, varscan2
- DGKK | c.3066C>A p.I1022= | Silent (SNP) | VAF 390/848 reads (46%) | called by muse, varscan2
- DLC1 | c.2673A>T p.S891= (on ENST00000276297 / NM_001348081.2; = p.S454= on NM_006094.5) | Silent (SNP) | VAF 110/495 reads (22%) | catalogued as rs998096728; called by muse, varscan2
- HLA-DMA | c.420C>T p.G140= | Silent (SNP) | VAF 285/813 reads (35%) | called by muse, varscan2
- IGFL2 | c.246T>C p.D82= (on ENST00000377693 / NM_001135113.2; = p.D93= on NM_001002915.2) | Silent (SNP) | VAF 118/498 reads (24%) | called by muse, varscan2
- KIR2DL4 | c.210C>G p.P70= (on ENST00000396284; = p.P31= on NM_001080770.2) | Silent (SNP) | VAF 236/524 reads (45%) | called by muse, varscan2
- MEFV | c.1107C>A p.P369= | Silent (SNP) | VAF 53/215 reads (25%) | catalogued as COSV99561367; called by muse, varscan2
- MYO7A | c.4653G>A p.A1551= | Silent (SNP) | VAF 158/527 reads (30%) | catalogued as rs1484578318; called by muse, varscan2
- NWD2 | c.804C>T p.R268= | Silent (SNP) | VAF 325/848 reads (38%) | called by muse, varscan2
- OR10H1 | c.222C>T p.T74= | Silent (SNP) | VAF 124/742 reads (17%) | catalogued as rs1320535487, COSV58472390; called by muse, varscan2
- OR10H2 | c.222C>T p.T74= | Silent (SNP) | VAF 175/1048 reads (17%) | catalogued as rs764681141, COSV59946208; called by muse, varscan2
- OR7G1 | c.666C>G p.V222= | Silent (SNP) | VAF 241/530 reads (45%) | called by muse, varscan2
- PCDHB5 | c.2013G>A p.P671= | Silent (SNP) | VAF 54/125 reads (43%) | called by muse, varscan2
- PCNT | c.9411G>A p.L3137= | Silent (SNP) | VAF 97/916 reads (11%) | catalogued as rs766666803; called by muse, varscan2
- PLOD3 | c.765C>T p.N255= | Silent (SNP) | VAF 246/544 reads (45%) | catalogued as rs375364238; called by muse, varscan2
- PNMA6E | c.1785A>G p.R595= (on ENST00000445091 / NM_001367770.1; = p.R317= on NM_001351293.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/200 reads (48%) | called by muse, varscan2
- SLC10A3 | c.1347C>T p.P449= | Silent (SNP) | VAF 242/536 reads (45%) | called by muse, varscan2
- C4B | c.2593-30C>T | Intron (SNP) | VAF 70/684 reads (10%) | called by muse, varscan2
- COX11 | chr17:54968683 C>G | 5'Flank (SNP) | VAF 50/430 reads (12%) | catalogued as rs761114175; called by muse, varscan2
- MPND | c.846+62G>A | Intron (SNP) | VAF 52/118 reads (44%) | catalogued as rs1241606128; called by muse, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 10/108 reads (9%) | called by muse, varscan2
- PRDX6 | c.*53G>T | 3'UTR (SNP) | VAF 113/312 reads (36%) | called by muse, varscan2
- THBS3 | c.2075-62G>T | Intron (SNP) | VAF 19/179 reads (11%) | called by muse, varscan2
- VSIR | c.*23G>C | 3'UTR (SNP) | VAF 160/598 reads (27%) | called by muse, varscan2
- VTI1B | c.175-33A>G | Intron (SNP) | VAF 41/128 reads (32%) | called by muse, varscan2
